Somatic mutation profile of tumor specimen BA2804D (aliquot aq-BA2804D) from BEATAML1.0 case 2101, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 87.1 years (31,813 days).
Specimen BA2804D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40ab36f4-f594-4563-aba4-000d7bd6b3a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2151D (Solid Tissue Normal), aliquot aq-BA2151D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9dd4204-3766-48d5-a7cf-797ddb0999b0

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD300C | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773477638; called by muse, varscan2
- PPP2R5C | c.1566C>A p.D522E | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV58271282; called by muse, mutect2
- CEBPA | c.485dup p.E163Gfs*7 | Frame Shift Ins (INS) | VAF 19/56 reads (34%) | called by pindel, varscan2
- SHF | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.098); called by muse, mutect2
- PXDNL | c.1608A>G p.G536= | Silent (SNP) | VAF 36/86 reads (42%) | called by mutect2, varscan2
- SYT12 | c.981G>T p.L327= | Silent (SNP) | VAF 40/88 reads (45%) | called by muse, varscan2
- CRHR2 | c.184+214G>T | Intron (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
